Somatic mutation profile of tumor specimen C3N-00831-01 (aliquot CPT0089020009) from CPTAC case C3N-00831, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 52.3 years (19,085 days).
Specimen C3N-00831-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4f70d02-909a-4b80-b003-ba21f2529f53.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00831-31 (Blood Derived Normal), aliquot CPT0089080002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70cc772d-393c-4981-883c-2d776fc5902d

The open-access MAF lists 46 somatic variants for this specimen: 33 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 9, Intron 4, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAT1 | c.1279C>T p.R427* | Nonsense Mutation (SNP) | VAF 13/111 reads (12%) | catalogued as rs761081587; called by muse, mutect2, varscan2
- CSMD3 | c.7030G>A p.D2344N (on ENST00000297405 / NM_001363185.1; = p.D2240N on NM_052900.3) | Missense Mutation (SNP) | VAF 93/410 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1315240161, COSV52163902; called by muse, mutect2, varscan2
- FHOD3 | c.3799C>T p.R1267W (on ENST00000359247 / NM_001281739.3; = p.R1284W on NM_025135.5) | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as rs770601848, COSV57167752; called by muse, mutect2, varscan2
- KLK13 | c.800C>A p.T267N | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.068); catalogued as rs752161872, COSV99335211; called by muse, varscan2
- MCF2L | c.3238G>A p.D1080N (on ENST00000375608; = p.D1048N on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs1426970953; called by muse, mutect2, varscan2
- MUC16 | c.31807C>T p.P10603S | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.354); catalogued as COSV67473750; called by muse, mutect2, varscan2
- NET1 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as rs1258973960; called by muse, mutect2
- NRXN1 | c.2323C>T p.R775C | Missense Mutation (SNP) | VAF 49/213 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs201387857, COSV100456926, COSV58479262; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDP2 | c.925C>A p.H309N | Missense Mutation (SNP) | VAF 51/226 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100305943; called by muse, mutect2, varscan2
- PTCHD4 | c.2074G>A p.V692I | Missense Mutation (SNP) | VAF 78/322 reads (24%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.642); catalogued as rs528776718, COSV59778280, COSV59779193; called by muse, varscan2
- RASA3 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1298837694; called by muse, mutect2
- THSD7B | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.019); catalogued as rs746487130; called by muse, mutect2
- VN1R4 | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 62/229 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60804949; called by muse, mutect2, varscan2
- ATP2B1 | c.2680A>C p.M894L | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- CNTNAP5 | c.1716C>A p.C572* | Nonsense Mutation (SNP) | VAF 16/136 reads (12%) | called by muse, mutect2, varscan2
- CTC1 | c.1561G>A p.V521I | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- DRD1 | c.616C>G p.P206A | Missense Mutation (SNP) | VAF 54/318 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM126A | c.1471C>T p.L491F | Missense Mutation (SNP) | VAF 51/254 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FGD2 | c.164C>A p.T55K | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FLG | c.3138C>G p.H1046Q | Missense Mutation (SNP) | VAF 163/669 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KNL1 | c.2514del p.I839* (on ENST00000346991 / NM_170589.5; = p.I813* on NM_144508.5) | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | called by mutect2, pindel, varscan2
- LPXN | c.176A>C p.Q59P | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MOB4 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MTHFR | c.302C>G p.P101R | Missense Mutation (SNP) | VAF 124/455 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- OR5I1 | c.99T>G p.F33L | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PANX3 | c.510C>A p.D170E | Missense Mutation (SNP) | VAF 35/282 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PSMB4 | c.304T>A p.Y102N | Missense Mutation (SNP) | VAF 72/294 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RPS6KA2 | c.1973A>T p.H658L | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SCNN1A | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SLIT3 | c.864T>A p.N288K | Missense Mutation (SNP) | VAF 56/347 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TBC1D9 | c.1175T>A p.V392E | Missense Mutation (SNP) | VAF 70/273 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- VPS13B | c.4114A>C p.K1372Q | Missense Mutation (SNP) | VAF 58/258 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF85 | c.1013G>C p.G338A | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- CAPN8 | c.1995C>T p.F665= | Silent (SNP) | VAF 56/247 reads (23%) | catalogued as rs746377638, COSV64814277; called by muse, mutect2, varscan2
- HSD17B1 | c.67C>T p.L23= | Silent (SNP) | VAF 32/151 reads (21%) | called by muse, mutect2, varscan2
- KCNH6 | c.1863G>T p.L621= | Silent (SNP) | VAF 29/85 reads (34%) | called by muse, mutect2, varscan2
- LGALSL | c.300T>G p.S100= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as COSV53230190; called by muse, mutect2, varscan2
- NBPF26 | c.2043G>C p.L681= (on ENST00000620612; = p.L419= on NM_001351372.1) | Silent (SNP) | VAF 39/86 reads (45%) | called by mutect2, varscan2
- PLEKHM2 | c.1458G>A p.G486= | Silent (SNP) | VAF 81/345 reads (23%) | called by muse, mutect2, varscan2
- SLC35G4 | c.510A>T p.I170= | Silent (SNP) | VAF 71/304 reads (23%) | catalogued as rs1396273662; called by muse, mutect2, varscan2
- ZDHHC11 | c.96C>T p.N32= | Silent (SNP) | VAF 80/374 reads (21%) | catalogued as rs772432837; called by muse, mutect2, varscan2
- ZNF586 | c.813T>C p.F271= | Silent (SNP) | VAF 100/435 reads (23%) | called by muse, mutect2, varscan2
- FAM228A | c.162+1346A>C | Intron (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- KEL | c.1315-16G>C | Intron (SNP) | VAF 99/504 reads (20%) | called by muse, mutect2, varscan2
- TFDP2 | c.187-5149G>T | Intron (SNP) | VAF 29/127 reads (23%) | called by muse, mutect2, varscan2
- ZBP1 | c.1094-2379_1094-2377del | Intron (DEL) | VAF 49/246 reads (20%) | called by pindel, varscan2
